TCGA case TCGA-EK-A2R9 — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/00ad0ffe-2105-4829-a495-1c2aceb5bb31

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, large cell, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 58.2 years (21,242 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC pathologic T: T1b1; AJCC pathologic N: N0; FIGO stage: Stage IB1; FIGO staging edition year: 1988; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes tested: 14; Lymphatic invasion present: Yes.

Follow-up (2 entries)
- Day 0 (preoperative): ECOG performance status: 0.
- Day 4 (preoperative): Disease response: With Tumor; ECOG performance status: 0.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 185 kg; Height: 162 cm; BMI: 70.5.
- Timepoint category: Prior to Diagnosis; Hysterectomy type: Radical Hysterectomy.

Exposures
- Exposure type: Tobacco.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EK-A2R9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 100 mg.
  Slide TCGA-EK-A2R9-01A-01-TS1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 65; Percent normal cells: 50; Percent necrosis: 3; Percent stromal cells: 7; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EK-A2R9-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Radical Total Abdominal Hysterectomy and BSO; Lymph nodes examined: Yes; Lymphovascular invasion: Present; Corpus involvement: Absent.
- Follow-up form: Lost to follow-up: Yes; Days from index date to performance status: 4.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 4 days; disease-specific survival: no event (censored), 4 days; progression-free interval: no event (censored), 4 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EK-A2R9-01A-11D-A18H-01): tumor purity 0.78, ploidy 2.1, whole-genome doublings 0.
